HCMI case HCM-CSHL-0584-C19 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b6aad54-f571-4cb0-bce2-a79447b9bb64

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1960; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 58.7 years (21,437 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N2a; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: Yes.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 6 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 71 days; Days to treatment end: 136 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 178 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 290 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 290 days.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 58.7 years (21,454 days); Days to diagnosis: 17 days.
   Pathology details: Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 340 days; Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CEA: 1.1 ng/mL.
- CEA: 1.3 ng/mL.
- KRAS mutation, nos: Negative.
- KRAS mutation, nos: Positive; Amino-acid change: KRAS wildtype (codons 12 \T\ 13.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76.2 kg; Height: 167.6 cm; BMI: 27.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0584-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0584-C19-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0584-C19-06A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 18; Percent stromal cells: 12; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
- Sample HCM-CSHL-0584-C19-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0584-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
